Somatic mutation profile of tumor specimen BA2616D (aliquot aq-BA2616D) from BEATAML1.0 case 2012, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.1 years (17,564 days).
Specimen BA2616D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1cfe6c7-d279-491c-bfd1-da930f77a8d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2897D (Solid Tissue Normal), aliquot aq-BA2897D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0a8607f-6cf6-456a-aad2-b13c2c8bafb2

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, RNA 1, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 76/349 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 32/105 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.3175G>A p.V1059M (on ENST00000372530 / NM_001198934.2; = p.V1031M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as rs199502499, COSV55084541; called by muse, mutect2, varscan2
- FLI1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs754322278, COSV61378190; called by muse, mutect2, varscan2
- FOXP1 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59557993; called by muse, mutect2, varscan2
- MAPRE3 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as rs749554114, COSV51869389; called by muse, mutect2, varscan2
- PHTF2 | c.1741C>T p.R581* (on ENST00000248550 / NM_001366089.1; = p.R543* on NM_020432.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as rs774201076; called by muse, mutect2, varscan2
- ZZEF1 | c.1400G>A p.C467Y | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs542727529; called by muse, mutect2, varscan2
- C17orf50 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GPD1 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2
- KMT2E | c.942del p.E315Rfs*2 | Frame Shift Del (DEL) | VAF 47/274 reads (17%) | called by mutect2, pindel, varscan2
- PDS5B | c.1520dup p.D508Gfs*4 | Frame Shift Ins (INS) | VAF 56/214 reads (26%) | called by mutect2, pindel, varscan2
- PLEKHA4 | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by mutect2, varscan2
- GKN1 | c.165C>T p.N55= | Silent (SNP) | VAF 50/186 reads (27%) | catalogued as rs145778324; called by muse, mutect2, varscan2
- HTR3C | c.75C>T p.G25= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs773852375, COSV59174422; called by muse, mutect2
- PYCR1 | c.252C>T p.A84= | Silent (SNP) | VAF 26/304 reads (9%) | catalogued as rs756495271; called by muse, mutect2
- SLC25A41 | c.1080G>T p.V360= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as rs1427973094; called by muse, mutect2
- TMEM150A | c.369G>C p.A123= (on ENST00000334462 / NM_001031738.3; = p.A70= on NM_153342.3) | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV57818160; called by muse, mutect2, varscan2
- TAAR3P | n.666T>A | RNA (SNP) | VAF 59/208 reads (28%) | called by muse, mutect2, varscan2
